Somatic mutation profile of tumor specimen TCGA-DZ-6132-01A (aliquot TCGA-DZ-6132-01A-11D-1961-08) from TCGA case TCGA-DZ-6132, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.6 years (25,417 days).
Specimen TCGA-DZ-6132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25c4a6c3-45c5-4083-869e-9fff94c75fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DZ-6132-11A (Solid Tissue Normal), aliquot TCGA-DZ-6132-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/667b2202-9453-4255-a6b7-b50c6bbb9815

The open-access MAF lists 119 somatic variants for this specimen: 101 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 17, Frame Shift Del 11, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 3, In Frame Del 2, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs786202724, CM1210646, CM990852, COSV59257346; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.1155C>G p.F385L | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV52946266; called by muse, mutect2, varscan2
- ACE | c.3020G>T p.R1007M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52007157; called by mutect2, varscan2
- ADCY8 | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs368729916; called by muse, mutect2, varscan2
- ALPL | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.755); catalogued as COSV66376226; called by muse, mutect2, varscan2
- ANPEP | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV55591690; called by muse, mutect2
- AP2B1 | c.1395A>C p.L465F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV51999671; called by muse, mutect2, varscan2
- ARHGAP29 | c.3269T>C p.L1090P | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as COSV53112215; called by muse, mutect2, varscan2
- ARHGEF12 | c.847A>T p.T283S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63104810; called by muse, mutect2, varscan2
- ATP1A2 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63403882; called by muse, mutect2, varscan2
- ATR | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV63386759; called by muse, mutect2, varscan2
- BCL2L14 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs1174739078, COSV53787785; called by muse, mutect2, varscan2
- BDP1 | c.6059A>T p.D2020V | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV62431575; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1428C>G p.D476E | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.038); catalogued as COSV57279748; called by muse, mutect2, varscan2
- CAMK1 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV56538842; called by muse, mutect2, varscan2
- CBLIF | c.378C>G p.N126K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV57238062; called by mutect2, varscan2
- CCDC38 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as rs903143089, COSV60183119; called by muse, mutect2
- CLTC | c.4940T>C p.V1647A | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV52247946; called by muse, mutect2, varscan2
- CRAT | c.621C>A p.H207Q | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV58877131; called by muse, mutect2, varscan2
- DENND4C | c.5656C>T p.P1886S (on ENST00000434457 / NM_001330640.2; = p.P1837S on NM_017925.7) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63008902; called by muse, mutect2, varscan2
- DLD | c.257T>C p.I86T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52738023; called by muse, mutect2, varscan2
- DLGAP2 | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70098612; called by muse, mutect2
- DNAJC13 | c.3287C>A p.P1096H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53450884; called by mutect2, varscan2
- DSCAM | c.3617T>A p.F1206Y | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV68027101; called by muse, mutect2, varscan2
- DSCAM | c.3616T>C p.F1206L | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.298); catalogued as COSV68027103; called by muse, mutect2, varscan2
- DYM | c.85A>C p.N29H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53985277; called by muse, mutect2, varscan2
- EIF4B | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV50403124, COSV50405266; called by muse, mutect2, varscan2
- ELN | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 123/338 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as COSV52710534; called by muse, mutect2, varscan2
- FADS1 | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.452); catalogued as COSV63520539; called by muse, mutect2, varscan2
- FAP | c.617T>A p.L206H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51862084; called by mutect2, varscan2
- FCGRT | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55529660; called by muse, mutect2, varscan2
- FKBP4 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50009132; called by muse, mutect2, varscan2
- GMPPA | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV58007000; called by muse, mutect2, varscan2
- GPD1L | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV56990152; called by muse, mutect2, varscan2
- GPNMB | c.1668C>G p.N556K (on ENST00000381990 / NM_001005340.2; = p.N544K on NM_002510.3) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV51698603; called by muse, mutect2, varscan2
- GPRASP1 | c.1222T>A p.W408R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64355630; called by muse, mutect2, varscan2
- GSTM1 | c.550T>G p.F184V | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59166666; called by muse, mutect2, varscan2
- HGSNAT | c.120C>G p.D40E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV65533526; called by muse, mutect2, varscan2
- KIR2DL4 | c.881C>T p.T294I (on ENST00000396284; = p.T255I on NM_001080772.2) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as rs1192868193, COSV58490995; called by muse, mutect2, varscan2
- LIFR | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54690714; called by muse, mutect2, varscan2
- MTMR4 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60200736; called by muse, mutect2, varscan2
- N4BP2 | c.2951C>G p.P984R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV54702054; called by muse, mutect2, varscan2
- NAPRT | c.503T>C p.M168T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV52785124; called by muse, mutect2
- NME7 | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV63167050; called by muse, varscan2
- NXPE3 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56289915; called by muse, varscan2
- ODF2L | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV54015618; called by muse, mutect2, varscan2
- OR2J3 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs765503496, COSV65849026; called by muse, mutect2, varscan2
- PCDHGC4 | c.77A>G p.Y26C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52752863, COSV52759452; called by muse, mutect2, varscan2
- PIK3R2 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV55848034; called by muse, mutect2, varscan2
- PLEKHA5 | c.2597A>G p.Y866C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1254529696, COSV54701207; called by muse, mutect2, varscan2
- POLQ | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 70/401 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51752393; called by muse, mutect2, varscan2
- PPFIA4 | c.2986A>G p.T996A (on ENST00000447715; = p.T997A on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV55315351; called by muse, mutect2, varscan2
- PUDP | c.103A>C p.N35H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as COSV66904079; called by muse, mutect2, varscan2
- RAB5B | c.539A>T p.K180M | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV64364933; called by mutect2, varscan2
- RAPSN | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as CM078172, COSV100100219; called by muse, varscan2
- RBBP6 | c.4556G>C p.R1519T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV60505271; called by muse, mutect2, varscan2
- RETREG2 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs766785806, COSV56087650, COSV99811332; called by muse, mutect2, varscan2
- RPGRIP1L | c.1544T>C p.M515T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV50907251; called by muse, mutect2, varscan2
- SERPINB2 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV55092585; called by muse, mutect2, varscan2
- SIDT2 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1314266605, COSV54057140; called by muse, mutect2, varscan2
- SLC2A5 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1484296148, COSV66236774; called by muse, mutect2, varscan2
- SLC35B2 | c.1065C>G p.I355M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51489408; called by muse, mutect2, varscan2
- SLC38A4 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV56967650; called by muse, mutect2, varscan2
- SOCS6 | c.593del p.N198Mfs*30 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as COSV67546481; called by mutect2, pindel, varscan2
- STAU1 | c.715A>T p.K239* (on ENST00000371856 / NM_001319135.1; = p.K158* on NM_004602.3) | Nonsense Mutation (SNP) | VAF 70/236 reads (30%) | catalogued as COSV61460324; called by muse, mutect2, varscan2
- STYK1 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV50013293; called by muse, mutect2, varscan2
- SUPT5H | c.2613C>A p.N871K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.206); catalogued as COSV63239850; called by muse, mutect2, varscan2
- SV2B | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV57699930; called by muse, mutect2, varscan2
- TEK | c.1903A>G p.S635G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV66229105; called by muse, mutect2, varscan2
- TESK2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334416022, COSV59152260; called by muse, mutect2, varscan2
- TMEM131L | c.4556C>T p.P1519L | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs932761613, COSV53644694; called by muse, mutect2, varscan2
- TMEM69 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as COSV63432677; called by muse, mutect2, varscan2
- TPST1 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59177173; called by mutect2, varscan2
- TRIM56 | c.1762T>C p.S588P | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV60159066; called by muse, mutect2, varscan2
- TRPC4 | c.1400C>A p.S467* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV58988887, COSV59000757; called by muse, mutect2, varscan2
- TTYH1 | c.639-2A>G p.X213_splice | Splice Site (SNP) | VAF 20/104 reads (19%) | catalogued as COSV56612016, COSV56616131; called by muse, mutect2, varscan2
- TTYH3 | c.927+2T>C p.X309_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | catalogued as COSV51860582; called by mutect2, varscan2
- TUT7 | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as COSV52895822; called by muse, mutect2, varscan2
- UBR2 | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV104425854, COSV65768657; called by muse, mutect2, varscan2
- ZBTB22 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV56469572; called by muse, mutect2, varscan2
- ZFYVE9 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV55094128; called by muse, mutect2, varscan2
- ZNF473 | c.2283G>C p.Q761H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV54523267; called by muse, mutect2, varscan2
- ZNF699 | c.1407C>G p.H469Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58025717; called by muse, mutect2, varscan2
- ZNF85 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs1364068895, COSV60214872; called by muse, varscan2
- ADAP2 | c.406del p.E136Kfs*15 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- ANK2 | c.1663del p.A555Pfs*4 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.2220del p.K740Nfs*12 | Frame Shift Del (DEL) | VAF 23/144 reads (16%) | called by mutect2, pindel, varscan2
- BAIAP2 | c.1502del p.X501_splice | Splice Site (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- BCR | c.470dup p.N157Kfs*111 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | called by mutect2, pindel
- CBLIF | c.375dup p.N126Qfs*3 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- GRIP1 | c.2861del p.F954Sfs*29 (on ENST00000359742 / NM_001379345.1; = p.F902Sfs*29 on NM_021150.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/185 reads (16%) | called by mutect2, pindel, varscan2
- INTS2 | c.3449_3451dup p.L1150dup | In Frame Ins (INS) | VAF 21/112 reads (19%) | called by mutect2, pindel, varscan2
- MYH15 | c.5494_5505del p.R1832_E1835del | In Frame Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- OR1N1 | c.903_913del p.L302Qfs*? | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- PLCD1 | c.1389_1391del p.D463del | In Frame Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- RCBTB1 | c.1300del p.D434Tfs*8 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel*, varscan2
- RPL24 | c.246dup p.T83Yfs*7 | Frame Shift Ins (INS) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- STOX1 | c.1629del p.F543Lfs*24 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- SYNPO | c.824del p.K275Rfs*7 (on ENST00000394243 / NM_001166208.2; = p.K31Rfs*7 on NM_007286.6) | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- WDR20 | c.89_96delinsTTA p.S30Ffs*55 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by pindel, varscan2*
- ZFP37 | c.403del p.L135Sfs*50 | Frame Shift Del (DEL) | VAF 23/178 reads (13%) | called by mutect2, pindel, varscan2
- ABCA4 | c.2209T>C p.L737= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV64673781; called by muse, mutect2
- ANAPC1 | c.1599T>C p.D533= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs763490262, COSV61976165; called by muse, mutect2, varscan2
- CBX1 | c.403C>T p.L135= | Silent (SNP) | VAF 54/237 reads (23%) | catalogued as COSV56681918; called by muse, mutect2, varscan2
- DMP1 | c.1293G>A p.E431= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV56820091; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1335A>T p.P445= | Silent (SNP) | VAF 46/282 reads (16%) | called by muse, varscan2
- KTN1 | c.244C>A p.R82= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV101254930, COSV68023629; called by muse, mutect2, varscan2
- LIPE | c.2673C>T p.T891= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV54923030; called by muse, mutect2, varscan2
- MACF1 | c.16104C>T p.A5368= (on ENST00000372915; = p.A3301= on NM_012090.5) | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs1470727626, COSV57122275; called by muse, mutect2
- MCPH1 | c.1320T>C p.A440= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs1563219081, COSV60913810; called by muse, mutect2, varscan2
- SCD5 | c.657C>G p.S219= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60295728; called by muse, mutect2, varscan2
- TMC8 | c.1266C>T p.S422= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs375990572; ClinVar: likely benign; called by muse, varscan2
- TNS1 | c.4524A>T p.P1508= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV50704563; called by muse, mutect2, varscan2
- UBE3D | c.897C>A p.S299= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99388528; called by mutect2, varscan2
- WASF2 | c.711T>C p.C237= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV71005600; called by muse, mutect2, varscan2
- ZNF143 | c.870T>G p.T290= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs373920789; called by muse, mutect2, varscan2
- ZNF223 | c.891C>T p.F297= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV71571902; called by muse, mutect2, varscan2
- ZYG11B | c.1410T>C p.A470= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV53753213; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331447 ins C | 5'Flank (INS) | VAF 8/36 reads (22%) | catalogued as rs769456057; called by mutect2, pindel
